Gene-level copy-number profile of specimen HCM-CSHL-0818-C56-85P from HCMI case HCM-CSHL-0818-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage IIIC; Tumor grade: High Grade; Age at diagnosis: 62.2 years (22,709 days).
Specimen HCM-CSHL-0818-C56-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d85a4295-6940-49cd-8d34-ad9c737c4a5d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0818-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/db1296a3-98b3-4994-b620-1fb60ce1b01f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 3,841; copy number 2: 20,368; copy number 3: 23,780; copy number 4: 6,126; copy number 5: 3,047; copy number 6: 746; copy number 7: 219; copy number 8: 49; copy number 9: 67; copy number 11: 1; copy number 12: 2; copy number 13: 2; copy number 14: 33; copy number 15: 26; copy number 18: 3.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,530,064–2,591,469, 6 genes (within-gene range 0–1): AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B.
- chr5:88,189,633–93,268,425, 55 genes: TMEM161B, TMEM161B-AS1, RNA5SP187, RPS3AP22, SNORA70, AC091826.1, LINC02060, AC091826.2, LINC00461, H3P23, MIR9-2, MEF2C-AS2, AC008525.1, AC008525.2, MEF2C, MEF2C-AS1, AC074131.1, LINC02161, AC113167.1, MIR3660, LINC01339, AC099554.1, AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3, ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2, PCBP2P3, AC093298.1, AC114316.1, AC124854.1, AC026780.1, AC026780.2, AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1, POLD2P1.
- chr17:31,094,927–31,382,116, 7 genes (within-gene range 0–1): NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 402 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,776,670–39,788,865, 61 genes, copy number 7–8 (broad region; genes not listed).
- chr1:42,903,232–43,270,936, 12 genes, copy number 7 (within-gene range 5–7): ATP6V1E1P1, SLC2A1, ATP6V0CP4, SLC2A1-AS1, AC099795.1, RNU6-880P, AL161637.1, FAM183A, EBNA1BP2, MIR6733, CFAP57, RNA5SP46.
- chr1:44,030,437–45,306,209, 48 genes, copy number 7 (within-gene range 5–7): AL139220.2, AL139220.1, KRT8P47, RN7SL479P, KLF17, AL356653.1, KLF18, AL359839.1, Y_RNA, OOSP1P1, AL035417.1, AL035417.2, DMAP1, ERI3, ERI3-IT1, RNU6-369P, RNF220, MIR5584, TMEM53, ARMH1, RNU5F-1, RNU5D-1, KIF2C, AL592166.1, RPS8, SNORD55, SNORD46, SNORD38A, SNORD38B, SNORD38B, RPS15AP11, BEST4, PLK3, TCTEX1D4, BTBD19, PTCH2, RNU5E-6P, AL136380.1, EIF2B3, RNA5SP47, CCNB1IP1P1, PPIAP35, MRPS17P1, HECTD3, UROD, ZSWIM5, OSTCP5, LINC01144.
- chr1:58,933,643–59,240,555, 1 gene, copy number 7 (within-gene range 4–7): LINC01358.
- chr1:59,131,932–62,319,434, 33 genes, copy number 7–8: HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2, PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P.
- chr3:66,378,797–66,637,412, 3 genes, copy number 8 (within-gene range 3–8): LRIG1, AC104440.1, RPL21P41.
- chr8:89,412,621–93,029,839, 48 genes, copy number 7: KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084.
- chr8:99,873,200–102,412,759, 67 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:104,489,231–106,752,694, 20 genes, copy number 8 (within-gene range 6–8): LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1.
- chr8:135,742,343–139,704,109, 16 genes, copy number 7–8: RNU1-35P, LINC02055, RNU6-144P, ZYXP1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9.
- chr17:47,807,372–48,123,601, 26 genes, copy number 7: OSBPL7, MRPL10, LRRC46, SCRN2, SP6, AC018521.3, AC018521.7, AC018521.5, SP2, SP2-AS1, AC018521.6, PNPO, AC018521.1, AC018521.2, PRR15L, CDK5RAP3, AC018521.4, COPZ2, MIR152, NFE2L1-DT, NFE2L1, AC004477.1, AC004477.2, CBX1, RNU6-1201P, SNX11.
- chr18:22,347,846–26,099,226, 64 genes, copy number 11–15 (broad region; genes not listed).
- chr21:44,217,014–44,244,993, 3 genes, copy number 18: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 3,841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
